Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6456, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6456-01A (Primary Tumor).

[page 1 of 2]
Case ID	Subject ID	Formatted Path Report
		STOMACH TISSUE CHECKLIST Specimen type: Gastric resection Tumor site: Stomach Tumor size: 8 x 6 x 1 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly to moderately differentiated Tumor extent: Adjacent structures (specify) - Lesser omentum Lymph nodes: 2/4 positive for metastasis (Intraabdominal 2/4) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 4fad9d17-eb58-440a-a5f5-b32b2c094254 (TCGA-BR-6456.19B7ABD4-0E23-49EB-99FC-4DC8CDECF766.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).